Gene-level copy-number profile of tumor specimen MP2PRT-PAYTJD-TTP1-A from MP2PRT case MP2PRT-PAYTJD, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.2 years (2,281 days).
Specimen MP2PRT-PAYTJD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d61bdd70-f808-479d-9789-fae0aaecc983.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAYTJD-NB1-B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5344315b-6c0d-43f4-bcf9-feefbc2a4e0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12; copy number 2: 52,210; copy number 3: 4,450; copy number 4: 1,567; copy number 5: 58; copy number 6: 100.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,263,476–148,288,951, 3 genes, copy number 5: RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 5: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:150,211,632–150,629,612, 25 genes, copy number 6: RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr1:151,169,986–151,459,494, 16 genes, copy number 6 (within-gene range 2–6): TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25.
- chr1:167,809,386–167,914,215, 1 gene, copy number 6 (within-gene range 4–6): ADCY10.
- chr1:169,367,970–169,396,540, 1 gene, copy number 6 (within-gene range 4–6): BLZF1.
- chr1:173,714,941–173,786,692, 2 genes, copy number 6: KLHL20, BX248409.1.
- chr1:175,297,080–175,743,616, 4 genes, copy number 6: RPS29P4, Z94057.1, TNR, TNR-IT1.
- chr1:183,186,238–183,245,127, 1 gene, copy number 6: LAMC2.
- chr1:187,506,838–189,133,292, 18 genes, copy number 5: AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.
- chr1:198,156,994–199,752,890, 19 genes, copy number 5: NEK7, PRR13P1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1.
- chr1:212,466,699–212,699,840, 10 genes, copy number 6: LINC02771, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3.
- chr1:214,348,700–214,871,716, 7 genes, copy number 5–6 (within-gene range 3–6): PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24.
- chr1:222,945,725–223,144,954, 3 genes, copy number 6 (within-gene range 4–6): NDUFB1P2, TLR5, AL359979.2.
- chr1:223,538,007–223,690,114, 3 genes, copy number 5: CAPN8, SNRPEP10, RNU6-1248P.
- chr1:223,856,579–223,864,851, 2 genes, copy number 6: PHBP11, ACTBP11.
- chr1:227,975,390–228,378,876, 21 genes, copy number 6 (within-gene range 4–6): CICP26, SEPTIN14P17, WNT3A, LINC02809, ARF1, MIR3620, C1orf35, MRPL55, FAM96AP2, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57, OBSCN-AS1, OBSCN, AL353593.1, AL353593.2, AL353593.3, AL670729.3.
- chr1:230,002,372–230,282,122, 3 genes, copy number 5 (within-gene range 2–5): LINC01736, GALNT2, AL136988.2.
- chr1:235,915,415–236,065,109, 5 genes, copy number 6: RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA.
- chr1:246,945,547–247,120,278, 8 genes, copy number 6 (within-gene range 4–6): ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, C1orf229, FGFR3P6.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
